Somatic mutation profile of tumor specimen BA2220D (aliquot aq-BA2220D) from BEATAML1.0 case 2394, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 23.8 years (8,695 days).
Specimen BA2220D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21554e4e-9f1d-4c59-b72b-ccd5078205e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2264D (Solid Tissue Normal), aliquot aq-BA2264D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63c6592d-198d-4cc5-9600-b8790bc7b4e5

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 4, Missense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HERC1 | c.11495G>A p.C3832Y | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- REXO2 | c.410G>C p.C137S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TTC37 | c.326+1G>T p.X109_splice | Splice Site (SNP) | VAF 28/302 reads (9%) | called by muse, mutect2
- ARMCX4 | c.1038+269C>A | Intron (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- BTN2A3P | n.1448-493C>A | Intron (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 6/13 reads (46%) | catalogued as rs73150876; called by mutect2, varscan2
- WDR1 | c.17-85A>T | Intron (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
